Somatic mutation profile of tumor specimen MP2PRT-PAPWMI-TMP1-A (aliquot MP2PRT-PAPWMI-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPWMI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (715 days).
Specimen MP2PRT-PAPWMI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c195cc9-d0cc-42a3-8840-6b9fe9ce3e3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWMI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWMI-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f01003-3928-457b-93a8-7553b5cf8c05

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/267 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKT1S1 | c.5C>T p.A2V (on ENST00000344175 / NM_001098633.4; = p.A22V on NM_032375.5) | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); catalogued as rs1341380427; called by muse, mutect2, varscan2
- DPY19L1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs960181495; called by muse, mutect2
- GRB14 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763464309, COSV55743185; called by muse, mutect2, varscan2
- KANK2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 66/455 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs958827310; called by muse, mutect2, varscan2
- PITPNM3 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs760328571; called by muse, mutect2, varscan2
- PTPRQ | c.1417C>T p.R473* (on ENST00000616559; = p.R431* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 12/386 reads (3%) | catalogued as rs1005570619, COSV57035523; called by muse, mutect2
- SHROOM2 | c.3259G>A p.V1087M | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745337866, COSV66607450; called by muse, mutect2
- RELN | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- APOE | c.465C>T p.L155= | Silent (SNP) | VAF 33/562 reads (6%) | catalogued as rs1356159599; called by muse, mutect2
- DACT1 | c.2139C>T p.Y713= | Silent (SNP) | VAF 60/584 reads (10%) | catalogued as rs778935261, COSV60019654; called by muse, mutect2, varscan2
- HMGB4 | c.288T>A p.P96= | Silent (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- VEGFC | c.318T>A p.T106= | Silent (SNP) | VAF 32/329 reads (10%) | called by muse, mutect2
